Somatic mutation profile of tumor specimen MBCProject_4647_T0_WES (aliquot MBCProject_4647_T0_WES_1) from CMI case MBCProject_4647, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.4 years (22,794 days).
Specimen MBCProject_4647_T0_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb6590c-228c-4841-abf9-f634e9180be0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4647_SALIVA (Saliva), aliquot MBCProject_4647_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c832c78b-bfbd-4f85-9939-6419d8139d8c

The open-access MAF lists 79 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Intron 4, 5'UTR 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, 5'Flank 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL3 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53298819, COSV53300607; called by muse, mutect2, varscan2
- CACNA2D3 | c.2812C>T p.L938F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs941796977; called by muse, mutect2, varscan2
- CADPS2 | c.2531C>G p.A844G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100460708; called by muse, mutect2
- CCDC168 | c.15086G>A p.C5029Y | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs913729113; called by muse, mutect2
- FAM131A | c.598C>T p.R200W (on ENST00000310585; = p.R231W on NM_144635.5) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as rs772407913; called by muse, mutect2, varscan2
- FBXL6 | c.1524C>G p.C508W | Missense Mutation (SNP) | VAF 239/503 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554852562; called by muse, mutect2, varscan2
- HSF5 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60200935; called by muse, mutect2
- KCNQ4 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as CM135001; called by muse, mutect2
- OR4N2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100270120, COSV60055300; called by muse, mutect2, varscan2
- PALB2 | c.1238del p.T413Nfs*11 | Frame Shift Del (DEL) | VAF 40/224 reads (18%) | catalogued as COSV99849127; called by mutect2, pindel, varscan2
- PAXBP1 | c.1724-1G>T p.X575_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99269487; called by muse, mutect2, varscan2
- SACS | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs752593308; called by muse, mutect2, varscan2
- SDK1 | c.2031C>A p.S677R | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs770971679; called by muse, mutect2, varscan2
- SP5 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs923972235, COSV64622931; called by muse, mutect2, varscan2
- TRPA1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs753381416, COSV100084697; called by muse, mutect2
- ACSL4 | c.1900G>A p.G634R (on ENST00000340800 / NM_022977.2; = p.G593R on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ADAMTS13 | c.3023G>T p.S1008I | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ADAMTS13 | c.3024C>A p.S1008R | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ARFGEF2 | c.4509G>T p.L1503F | Missense Mutation (SNP) | VAF 54/700 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- CACNA1E | c.2334G>C p.W778C | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CHIC2 | c.210A>T p.R70S | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILP | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- COG4 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL14A1 | c.2941T>A p.S981T | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL14A1 | c.2942C>A p.S981Y | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- COL4A1 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A3 | c.1504del p.H502Ifs*8 | Frame Shift Del (DEL) | VAF 41/216 reads (19%) | called by pindel, varscan2
- DNAH17 | c.10529A>T p.K3510M | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- FAR2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GJA3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 127/501 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GON4L | c.5631+5G>A | Splice Region (SNP) | VAF 87/433 reads (20%) | called by muse, mutect2, varscan2
- HMCN2 | c.12395G>T p.R4132L | Missense Mutation (SNP) | VAF 149/702 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INSRR | c.2068T>C p.C690R | Missense Mutation (SNP) | VAF 114/520 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF6 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KRT32 | c.80G>T p.S27I | Missense Mutation (SNP) | VAF 122/573 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- LTBP4 | c.1067A>T p.E356V (on ENST00000308370 / NM_001042544.1; = p.E319V on NM_003573.2) | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF8 | c.2903G>A p.W968* (on ENST00000251268 / NM_001271938.2; = p.W901* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 118/465 reads (25%) | called by muse, mutect2, varscan2
- NCK1 | c.644A>C p.D215A | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NEK11 | c.1778G>C p.R593T | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 23/266 reads (9%) | called by muse, mutect2
- PWWP2A | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- RABEPK | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- RAPGEF3 | c.565C>T p.P189S (on ENST00000389212; = p.P147S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RHBDL1 | c.302A>T p.E101V (on ENST00000219551 / NM_001318733.2; = p.E36V on NM_001278720.2) | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2
- ROBO1 | c.3820A>C p.M1274L | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SACS | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SBK3 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35F5 | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC9A3R1 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TLN2 | c.7165C>T p.Q2389* | Nonsense Mutation (SNP) | VAF 86/350 reads (25%) | called by muse, mutect2, varscan2
- TMLHE | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- VIRMA | c.4007A>T p.N1336I | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2
- ZNF469 | c.3995A>C p.N1332T (on ENST00000437464; = p.N1360T on NM_001367624.2) | Missense Mutation (SNP) | VAF 106/967 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ACSL1 | c.240G>A p.E80= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- CC2D2A | c.1698G>A p.E566= | Silent (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- CD207 | c.645C>G p.T215= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as rs533675173; called by muse, mutect2, varscan2
- CD33 | c.987C>G p.A329= | Silent (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
- CLCN1 | c.2631G>A p.G877= | Silent (SNP) | VAF 64/240 reads (27%) | called by muse, mutect2, varscan2
- COL27A1 | c.5130C>T p.N1710= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs1405798136, COSV61922673; called by muse, mutect2
- CXCL6 | c.51C>T p.S17= | Silent (SNP) | VAF 70/529 reads (13%) | catalogued as rs775906428; called by muse, mutect2, varscan2
- DDX27 | c.1629C>T p.T543= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV65608915; called by muse, mutect2, varscan2
- FMO1 | c.1096C>T p.L366= | Silent (SNP) | VAF 84/204 reads (41%) | catalogued as COSV61447072; called by muse, mutect2, varscan2
- GABBR1 | c.954C>A p.V318= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV63542270; called by muse, mutect2
- LMTK2 | c.210G>A p.K70= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- LSP1 | c.6G>A p.A2= | Silent (SNP) | VAF 91/375 reads (24%) | catalogued as rs199891763; called by muse, mutect2, varscan2
- PLCB4 | c.2202A>T p.I734= | Silent (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- SARDH | c.2217T>C p.I739= | Silent (SNP) | VAF 81/354 reads (23%) | called by muse, mutect2, varscan2
- SFRP2 | c.465C>G p.L155= | Silent (SNP) | VAF 63/208 reads (30%) | called by muse, mutect2
- TBCD | c.207G>A p.E69= | Silent (SNP) | VAF 61/275 reads (22%) | called by muse, mutect2, varscan2
- TRIOBP | c.319C>A p.R107= | Silent (SNP) | VAF 41/266 reads (15%) | catalogued as rs376056274; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498988 T>A | 5'Flank (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- COPRS | c.99+318C>A | Intron (SNP) | VAF 78/632 reads (12%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.-22G>A | 5'UTR (SNP) | VAF 24/511 reads (5%) | catalogued as rs544227512, COSV100428980; called by muse, mutect2
- KRT14 | c.-10C>A | 5'UTR (SNP) | VAF 286/679 reads (42%) | called by muse, mutect2, varscan2
- LUC7L | c.61+347G>A | Intron (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 20/332 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- SAMSN1 | c.465+1377C>G | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- SLC26A8 | c.-106del | 5'UTR (DEL) | VAF 49/194 reads (25%) | called by mutect2, pindel, varscan2
- TMCO3 | c.*81_*85del | 3'UTR (DEL) | VAF 73/292 reads (25%) | called by mutect2, pindel, varscan2
